Gene-level copy-number profile of tumor specimen HCM-BROD-0874-C43-06A from HCMI case HCM-BROD-0874-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.5 years (21,744 days).
Specimen HCM-BROD-0874-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 267739c1-7bc4-4f79-a7d0-10c2199aa175.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0874-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/13bf6211-dbd6-456f-bee9-a6d518dff95c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 5; copy number 2: 5,330; copy number 3: 16,162; copy number 4: 24,278; copy number 5: 5,820; copy number 6: 3,792; copy number 7: 1,330; copy number 8: 1,474; copy number 9: 190; copy number 10: 3; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,143,820–137,173,648, 1 gene: IL22RA2.
- chr9:39,734,670–39,741,193, 2 genes: RAB28P1, RBPJP5.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 194 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 13: CFHR3.
- chr6:53,235,621–58,438,364, 73 genes, copy number 9 (broad region; genes not listed).
- chr9:39,886,861–39,892,895, 3 genes, copy number 10: RN7SL763P, SNORA70, CR769767.1.
- chr10:46,578,217–50,625,163, 97 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr22:15,282,557–15,644,330, 18 genes, copy number 9: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7.
- chr22:15,699,361–15,703,403, 2 genes, copy number 9 (within-gene range 8–9): POTEH-AS1, RNU6-816P.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
